Gene-level copy-number profile of tumor specimen TCGA-DX-A1L2-01A from TCGA case TCGA-DX-A1L2, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 78.6 years (28,692 days).
Specimen TCGA-DX-A1L2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.06c30ed9-2bdd-4ea5-8afd-2be787152641.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A1L2-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dd4566ff-a309-4ccb-b6ef-4cc42d28122c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 1,827; copy number 2: 15,003; copy number 3: 25,190; copy number 4: 11,829; copy number 5: 3,496; copy number 6: 648; copy number 7: 594; copy number 8: 231; copy number 9: 67; copy number 10: 51; copy number 11: 114; copy number 12: 86; copy number 13: 179; copy number 14: 121; copy number 15: 41; copy number 16: 64; copy number 17: 50; copy number 18: 54; copy number 20: 53; copy number 21: 71; copy number 22: 9; copy number 24: 3; copy number 25: 10; copy number 31: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A1L2-01A-22D-A24M-01): tumor purity 0.54, ploidy 3.11, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–3): MTAP, AL359922.1.
- chr9:21,858,910–21,995,301, 5 genes: AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,805 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–148,288,951, 167 genes, copy number 7–15 (broad region; genes not listed).
- chr1:148,295,180–148,358,686, 7 genes, copy number 15: LINC02806, AC245100.1, AC245100.5, Y_RNA, MIR5087, RNVU1-21, AC245100.6.
- chr1:150,268,200–150,476,566, 5 genes, copy number 11: C1orf54, CIART, MRPS21, PRPF3, RPRD2.
- chr1:152,168,125–152,445,456, 1 gene, copy number 7 (within-gene range 5–13): FLG-AS1.
- chr1:152,212,076–154,288,527, 124 genes, copy number 7–17 (broad region; genes not listed).
- chr1:156,308,968–161,678,654, 240 genes, copy number 7–21 (broad region; genes not listed).
- chr1:161,766,320–162,023,854, 3 genes, copy number 12 (within-gene range 5–12): ATF6, AL391825.1, OLFML2B.
- chr1:162,069,691–162,529,631, 12 genes, copy number 17 (within-gene range 4–17): NOS1AP, AL450163.1, MIR4654, AL512785.1, RNA5SP61, MIR556, AL512785.2, SPATA46, C1orf226, SH2D1B, SLAMF6P1, UHMK1.
- chr1:163,068,775–172,444,086, 198 genes, copy number 11–25 (within-gene range 2–25) (broad region; genes not listed).
- chr3:4,896,809–5,099,861, 6 genes, copy number 7: BHLHE40-AS1, BHLHE40, RNF10P1, UBTFL8, Y_RNA, AC090955.1.
- chr3:10,081,317–22,382,929, 189 genes, copy number 7–13 (within-gene range 4–13) (broad region; genes not listed).
- chr3:23,878,981–32,786,116, 108 genes, copy number 8–10 (broad region; genes not listed).
- chr5:602,620–4,147,429, 72 genes, copy number 12 (broad region; genes not listed).
- chr5:6,839,460–22,853,344, 238 genes, copy number 7–11 (within-gene range 5–11) (broad region; genes not listed).
- chr5:25,909,503–26,013,025, 3 genes, copy number 14: MSNP1, AC113370.1, RNU4-43P.
- chr5:32,646,564–36,242,279, 63 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr5:36,861,736–37,753,435, 18 genes, copy number 7: AC026741.1, NIPBL-DT, NIPBL, KRT18P31, RPS4XP6, CPLANE1, RBISP2, OFD1P17, RN7SL37P, AC025449.2, AC025449.1, NUP155, RNU7-75P, AC117532.1, WDR70, KCTD9P5, RNU6-1190P, RNU6-484P.
- chr5:37,812,677–37,840,041, 1 gene, copy number 7: GDNF.
- chr7:116,524,994–118,513,830, 47 genes, copy number 7: CAV1, AC006159.1, AC006159.2, COMETT, MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2, AC002542.3, AC002542.1, AC002542.5, AC002542.4, AC006326.1, MTND4P6, MTCYBP6, WNT2, CFTR, AC002465.1, ASZ1, ANKRD49P4, AC000111.2, CFTR-AS1, AC000111.1, AC000061.1, CTTNBP2, AC007568.1, AC003084.1, LSM8, ANKRD7, AC002529.1.
- chr7:121,736,443–122,995,700, 18 genes, copy number 7–16: RN7SKP277, PNPT1P2, PTPRZ1, AASS, RNU7-154P, AC015983.2, AC006020.1, AC015983.1, FEZF1, FEZF1-AS1, CADPS2, AC004594.1, AC006463.1, RPS26P31, RNF133, RNF148, AC004986.1, TAS2R16.
- chr7:125,917,871–127,602,144, 19 genes, copy number 7–31 (within-gene range 4–31): AC003975.1, AC000372.1, GRM8, AC002057.2, AC000374.1, AC002057.1, AC000367.1, AC000362.1, MIR592, GRM8-AS1, PRELID3BP10, ZNF800, AC000123.2, AC000123.1, AC000123.3, AC000124.1, GCC1, ARF5, FSCN3.
- chr7:128,443,449–131,497,694, 115 genes, copy number 7–31 (broad region; genes not listed).
- chr8:17,864,380–18,401,218, 15 genes, copy number 9: FGL1, AC087273.1, AC087273.2, PCM1, ASAH1, AC124242.1, AC124242.2, AC124242.3, NAT1, MTND4LP26, NATP, AC025062.1, AC025062.3, AC025062.2, NAT2.
- chr8:19,091,703–19,145,449, 1 gene, copy number 10 (within-gene range 2–10): AC100849.2.
- chr8:28,767,661–28,890,242, 1 gene, copy number 10 (within-gene range 1–10): INTS9.
- chr8:28,890,395–29,632,644, 16 genes, copy number 10: HMBOX1, Metazoa_SRP, HMBOX1-IT1, RNA5SP260, AC108449.2, KIF13B, AC108449.3, AC108449.1, HMGB1P23, DUSP4, AC084262.2, AC084262.1, AC084026.2, AC084026.1, AC084026.3, RPL17P33.
- chr14:26,208,036–29,392,048, 32 genes, copy number 7: CYB5AP5, NOVA1, AL079343.1, LINC02588, AL110292.1, LINC02294, LINC02293, AL132718.1, MIR4307HG, MIR4307, AL390334.1, LINC00645, MIR3171, BNIP3P1, AL139023.1, RPL26P3, LINC02300, EIF4A1P12, BTF3P2, FOXG1-AS1, AL049777.1, FOXG1, LINC01551, LINC02282, LINC02281, LINC02327, AL122126.1, LINC02326, Y_RNA, AL135878.1, RNU6-864P, AL133166.1.
- chr14:68,421,698–68,736,678, 8 genes, copy number 12: PPIAP6, AL121820.3, AL121820.2, AL121820.1, RPL12P7, AL133313.1, AL132986.1, RNU6-921P.
- chr17:61,354,763–63,005,152, 48 genes, copy number 11: AC005746.3, AC005746.2, AC005746.1, TBX2-AS1, TBX2, LINC02875, TBX4, AC005901.1, NACA2, BRIP1, INTS2, Y_RNA, MED13, AC018628.1, RN7SL800P, AC018628.2, Y_RNA, Y_RNA, POLRMTP1, AC053481.3, AC053481.4, TBC1D3P2, AC053481.2, AC053481.1, EFCAB3, AC008026.2, RNU7-52P, RPS23P7, METTL2A, TLK2, AC008026.1, AC008026.3, AC080038.2, AC080038.1, MRC2, Y_RNA, AC080038.3, RNU6-446P, AC005821.1, MARCHF10, AC005821.2, MARCHF10-DT, PRELID3BP3, AC005972.3, MIR633, TRMT112P3, AC005972.1, AC005972.2.
- chr17:63,088,162–63,089,197, 1 gene, copy number 11: AC006270.2.
- chr19:9,019,344–9,083,398, 2 genes, copy number 7: BOLA3P2, OR1M4P.
- chr19:14,950,034–15,552,317, 27 genes, copy number 7: SLC1A6, CCDC105, CASP14, OR1I1, SYDE1, ILVBL, AC003956.1, OR10B1P, RNU6-782P, NOTCH3, MIR6795, AC004257.1, EPHX3, BRD4, AC005776.1, AC005776.2, AKAP8, AC005785.1, AKAP8L, AC005785.2, AC006128.1, WIZ, MIR1470, RASAL3, PGLYRP2, CYP4F22, AC011492.1.

Autosomal genes at a single copy (total copy number 1): 103. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
